Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5J8, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5J8-01A (Primary Tumor).

[page 1 of 2]
Patient Name:

Sex: Male

ICD-O-3
Carcinoma, Adrenal Cortical
8370/5
Site: ④ Adrenal Gland
Cortex C74.0
JWD 1/30/13

Macroscopy

One vessel containing a material immersed in formaldehyde solution, described as following: product of en-bloc resection of the left kidney and an adrenal mass, weighting 2468.9 g and measuring 24 x 20 x 10 cm totally surrounded by fatty tissue. The adrenal mass measures 19 x 17 x 12.4 cm with a heterogeneous cut surface, characterized by multilobulated areas with a yellow color and some purple spots. Multiple areas of necrosis are evident in roughly 20% of the mass. The left kidney is inferiorly displaced by the mass and measures 10 x 6.5 x 5.5 cm. No macroscopic changes are evident. The ureter is somewhat dilated and measures 8.5 x 1.5 cm. The surgical margins were stained with green indian ink.

Conclusion:

Product of left nephrectomy and left adrenal mass resection: Adrenocortical carcinoma with the following features:

- Largest diameter – 19 cm.
- Nuclear grade (Fuhrman) – 4
- Diffuse architectural pattern – present
- Clear cells in < 25% of the neoplasm – present
- Areas on necrosis – present
- Mitotic count – 28 in 10 H.P.F.
- Atypical mitosis – present
- Capsular invasion – present
- Venous invasion – present

[page 2 of 2]
- Sinusoidal invasion – not detected
- WEISS SCORE = 8
- Renal parenchyma without evidence of neoplastic infiltration

CR: w/	h/ 1/4/13	Yes	No
Corrected Discrepancy			
Interpretation Discrepancy			
Pathologic Discrepancy			
Final Histopathologic Report			

Source: NCI Genomic Data Commons file 1258bdc6-7086-4d80-80ae-1b78c3994410 (TCGA-OR-A5J8.EA68CD7A-9308-40CD-BB52-CEB36334A146.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).